Somatic mutation profile of tumor specimen MP2PRT-PASRGZ-TMP1-A (aliquot MP2PRT-PASRGZ-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASRGZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,948 days).
Specimen MP2PRT-PASRGZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d480d355-5dcc-483f-b730-8a977817673f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRGZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRGZ-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afbc914f-0dc7-4a33-b5c9-ff74b2fd214d

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1861A>C p.N621H (on ENST00000288602 / NM_001374244.1; = p.N581H on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs180177040, CM060878, COSV56062673, COSV56077649, COSV56286119; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 172/351 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FREM1 | c.5801G>A p.R1934H | Missense Mutation (SNP) | VAF 89/107 reads (83%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs778288375; called by muse, mutect2, varscan2
- KLHL34 | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 310/674 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV65279490; called by muse, varscan2
- PIK3CG | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 169/416 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV100783219, COSV63249288; called by muse, mutect2, varscan2
- LRRC66 | c.643T>C p.F215L | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RYR3 | c.9285G>A p.T3095= (on ENST00000389232; = p.T3096= on NM_001036.6) | Silent (SNP) | VAF 104/236 reads (44%) | catalogued as rs756969948, COSV66785123; called by muse, mutect2, varscan2
- ZFHX4 | c.1158G>A p.A386= | Silent (SNP) | VAF 437/640 reads (68%) | catalogued as rs1314056291, COSV99256949; called by muse, mutect2, varscan2
